Somatic mutation profile of tumor specimen 0DEA0T from CCDI case PBBPME, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,243 days).
Specimen 0DEA0T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 959c4da9-ad8d-44df-891d-5830312f0da5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEA0K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6622358f-307f-4b15-a48c-8ffd051f7ddd

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/491 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CERT1 | c.1281_1283del p.K429del (on ENST00000405807 / NM_001130105.1; = p.K301del on NM_005713.3) | In Frame Del (DEL) | VAF 29/260 reads (11%) | catalogued as rs1427143564; called by mutect2, varscan2
- ITIH6 | c.3638G>A p.R1213H | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs375393223, COSV54487088, COSV54490869; called by mutect2, varscan2
- NLRP14 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 27/538 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs766265519, COSV55064484; called by muse, mutect2
- OPA1 | c.2179-2A>G p.X727_splice (on ENST00000361510 / NM_130837.3; = p.X672_splice on NM_015560.3) | Splice Site (SNP) | VAF 29/177 reads (16%) | catalogued as rs754194210; called by muse, mutect2, varscan2
- SP140 | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 32/590 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV59450118; called by muse, mutect2
- TCAF1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs149141329; called by muse, mutect2, varscan2
- AMFR | c.612C>G p.C204W | Missense Mutation (SNP) | VAF 28/893 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- IDO1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- MYPN | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 101/851 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- RNF19B | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 32/532 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGEF9 | c.1422G>A p.P474= | Silent (SNP) | VAF 81/236 reads (34%) | catalogued as rs782097997, COSV53645597; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA10 | c.792C>T p.N264= | Silent (SNP) | VAF 81/623 reads (13%) | catalogued as rs782759448, COSV56485927; called by muse, mutect2, varscan2
- SH3BP4 | c.2868G>A p.A956= | Silent (SNP) | VAF 49/329 reads (15%) | catalogued as rs368908066; called by muse, mutect2, varscan2
- IQCG | c.-59-5699C>A | Intron (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
